Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A4KQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A4KQ-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----
THYROID (RIGHT LOBECTOMY):

SPECIMEN TYPE:
Right lobectomy

TUMOR SITE:
Right lobe

HISTOLOGIC TYPE:
Papillary carcinoma, follicular variant
(Encapsulated) $\geq 99\%$ follicular *pw JSC*

ICD - 0 - 3
Carcinoma, papillary, follicular variant
8340/3
Site: thyroid, nos c73.9
pw
10/3/12

TUMOR SIZE:
4.0 cm

FOCALITY:
Unifocal

LYMPH NODES:
None submitted

EXTENT OF INVASION (7th Edition AJCC):
PRIMARY TUMOR:
pT2: tumor >2 cm but <=4 cm, limited to thyroid

REGIONAL LYMPH NODES:
pNx: Cannot be assessed

DISTANT METASTASIS:
pMx: Cannot be assessed

MARGINS:
Margins are uninvolved
Distance of invasive carcinoma from nearest
margin: 1 mm (specify: anterior)

VENOUS/LYMPHATIC INVASION:
Absent

ADDITIONAL PATHOLOGIC FINDINGS:
Nodular hyperplasia

pw
10/3/12

Source: NCI Genomic Data Commons file a413324f-77d7-48ac-b643-4056ee1153c5 (TCGA-ET-A4KQ.AE832FB1-0B21-463D-A8F5-68CF8EFDAC62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).